Surgical pathology report (de-identified scan), TCGA case TCGA-J4-8198, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-J4-8198-01A (Primary Tumor).

[page 1 of 5]
MRN

Name

Encounter
Number

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected
Time Reported
Ordering Provider
StatusTime Received
Order Number

Results

Final

Source of Specimen

- A. TISSUE OVER PROSTATE-
B. PROSTATE SEMINAL VESICLES AND VAS DEFERENS-

FINAL DIAGNOSIS:

- A. TISSUE OVER PROSTATE-
ADIPOSE TISSUE, NO LYMPH NODES OR TUMOR FOUND.
B. PROSTATE SEMINAL VESICLES AND VAS DEFERENS-

ADENOCARCINOMA OF PROSTATE WITH INVASION OF RIGHT SEMINAL
VESICLE(S).

EXTRAPROSTATIC SOFT TISSUE: NOT INVOLVED.

TUMOR SITE: BOTH LOBES AND APICES

SPECIMEN TYPE: RADICAL PROSTATECTOMY.

WEIGHT: 30 GRAMS. SIZE: 4.5 x 3.5 x 3.5 CM.

GLEASON SCORE (PRIMARY + SECONDARY PATTERN): 4 + 3 = 7/10.

TERTIARY PATTERN: IS PRESENT, GLEASON GRADE 5/5.

SEVERITY IN EXTENT OF TUMOR: 5 /5.

(1: <5%; 2: 5-15%; 3: 15-30%; 4: 30-50%; 5: > 50% tissue
involvement).

[page 2 of 5]
DOMINANT NODULE (AT LEAST 1 CM IN SIZE): NOT PRESENT.

TREATMENT EFFECT ON CARCINOMA: NOT IDENTIFIED.

TNM STAGE: pT3b, pNX, pMX.

(N0: negative node; N1: positive regional node)

LYMPHATIC (SMALL VESSEL) INVASION: NOT SEEN.

PERINEURAL INVASION: NOT PRESENT.

MARGIN STATUS:

POSITIVE INKED MARGINS: NA PROSTATE, NA TRANSECTED.

POSITIVE SHAVED MARGIN: NA BLADDER NECK, FOCAL.

OTHER MARGINS ARE CLEAR.

Case Clinical Information

PROSTATE CANCER

Gross Description

A. Received in formalin labeled with the patient's name and "tissue over prostate" is a 6 cm aggregate of tan/yellow fatty tissue with no palpable masses identified. The entire specimen is submitted in A1-A4.

B. Received in formalin labeled with the patient's name and "prostate, seminal vesicles and vas deferens" is a radical prostatectomy specimen which includes a 30 gram prostate gland with attached right seminal vesicle and vas deferens. The left seminal vesicle and vas deferens are free floating in the container. The prostate gland measures 4.5 x 3.5 x 3.5 cm and has a shaggy capsule that is disrupted at the bladder margin and has been previously inked black on the left and blue on the right. The right seminal vesicle is somewhat disrupted measuring 3 x 1 x 1 cm. The right vas measures 2.8 cm in length. The vas deferens and seminal vesicle in the container measures 3.5 x 2 x 1 cm. The inferior prostate is sectioned transversely, removed from the rest of the specimen and sectioned from anterior to posterior following the plane of the urethra. The remaining gland is serially sectioned transversely and shows a firm, focally nodular parenchyma. The seminal vesicles and vasa deferentia show no gross abnormalities. Section code is as follows: inferior prostate demonstrating

Prepared

[page 3 of 5]
apical margin submitted entirely anterior to posterior in B1-B8
; perpendicular shaves of bladder margin B9-B10; complete
section of mid gland anterior B11-B12; posterior B13-B14;
complete section of upper third of gland, anterior B15-B16;
posterior B17-B18; remainder of the posterior gland entirely
submitted in B19-B20; right seminal vesicle and vas deferens
B21; additional left seminal vesicle and vas deferens in
container B22; tumor taken at research B23; normal take for
research B24.

Procedure

A. AA ROUTINE H&E X1 BLOCK.1
H&E X1
A. AA ROUTINE H&E X1 BLOCK.2
H&E X1
A. AA ROUTINE H&E X1 BLOCK.3
H&E X1
A. AA ROUTINE H&E X1 BLOCK.4
H&E X1
B. AA ROUTINE H&E X1 BLOCK.1
H&E X1
B. AA ROUTINE H&E X1 BLOCK.2
H&E X1
B. AA ROUTINE H&E X1 BLOCK.3
H&E X1
B. AA ROUTINE H&E X1 BLOCK.4
H&E X1
B. AA ROUTINE H&E X1 BLOCK.5
H&E X1
B. AA ROUTINE H&E X1 BLOCK.6
H&E X1
B. AA ROUTINE H&E X1 BLOCK.7
H&E X1
B. AA ROUTINE H&E X1 BLOCK.8
H&E X1
B. AA ROUTINE H&E X1 BLOCK.9
H&E X1
B. AA ROUTINE H&E X1 BLOCK.10
H&E X1
B. AA ROUTINE H&E X1 BLOCK.11
H&E X1
B. AA ROUTINE H&E X1 BLOCK.12
H&E X1
B. AA ROUTINE H&E X1 BLOCK.13

Prepared

[page 4 of 5]
H&E X1
B. AA ROUTINE H&E X1 BLOCK.14
H&E X1
B. AA ROUTINE H&E X1 BLOCK.15
H&E X1
B. AA ROUTINE H&E X1 BLOCK.16
H&E X1
B. AA ROUTINE H&E X1 BLOCK.17
H&E X1
B. AA ROUTINE H&E X1 BLOCK.18
H&E X1
B. AA ROUTINE H&E X1 BLOCK.19
H&E X1
B. AA ROUTINE H&E X1 BLOCK.20
H&E X1
B. AA ROUTINE H&E X1 BLOCK.21
H&E X1
B. AA ROUTINE H&E X1 BLOCK.22
H&E X1
B. AA ROUTINE H&E X1 BLOCK.23
H&E X1
B. AA ROUTINE H&E X1 BLOCK.24
H&E X1

Source: NCI Genomic Data Commons file 30cd2b75-6bfd-4314-b20b-3fb466e242f6 (TCGA-J4-8198.C61B1DA1-F0D2-48C9-AC71-5967799DEF29.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).